Somatic mutation profile of tumor specimen MP2PRT-PASZBR-TMP1-A (aliquot MP2PRT-PASZBR-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASZBR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,357 days).
Specimen MP2PRT-PASZBR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74bfb52e-cdee-4df2-8072-0882eaa807a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZBR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZBR-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e1041cd-78c2-428a-8355-d8f05bb5e53b

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 66/253 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PCDH11X | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 104/476 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs760129843, COSV53441719, COSV53494306; called by muse, mutect2, varscan2
- SGCZ | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs751791396, COSV66023617; called by muse, varscan2
- SLC4A11 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233324021, CM137450, COSV66261703; called by muse, mutect2, varscan2
- PAIP2B | c.72C>T p.H24= | Silent (SNP) | VAF 54/379 reads (14%) | catalogued as rs780219227, COSV54909590; called by muse, mutect2
